Gene-level copy-number profile of tumor specimen TCGA-X9-A971-01A from TCGA case TCGA-X9-A971, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 52.6 years (19,207 days).
Specimen TCGA-X9-A971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a82fdfae-7b34-48ca-b43d-ee816193dafc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X9-A971-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e89efee6-793a-4b6d-9d54-4beeab810cdc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 35; copy number 2: 8,324; copy number 3: 16,393; copy number 4: 26,105; copy number 5: 4,953; copy number 6: 1,015; copy number 7: 1,186; copy number 8: 933; copy number 9: 759; copy number 10: 16; copy number 11: 3; copy number 15: 2; copy number 16: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X9-A971-01A-11D-A386-01): tumor purity 0.93, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,389,567–50,125,720, 45 genes (within-gene range 0–2): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.
- chr17:6,322,413–6,640,711, 9 genes (within-gene range 0–2): BTF3P14, AC055872.2, AIPL1, AC055872.1, PIMREG, PITPNM3, Metazoa_SRP, KIAA0753, RNA5SP435.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 803 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:57,595,940–57,658,800, 2 genes, copy number 15: AC107396.1, AC093725.2.
- chr4:61,201,258–62,078,335, 1 gene, copy number 11 (within-gene range 2–11): ADGRL3.
- chr4:61,420,246–61,775,850, 2 genes, copy number 11: AC020741.1, AC108161.1.
- chr14:36,298,564–38,041,442, 30 genes, copy number 9 (within-gene range 8–9): MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517.
- chr14:53,917,270–54,902,826, 16 genes, copy number 10 (within-gene range 8–10): AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3.
- chr14:73,458,850–75,051,532, 72 genes, copy number 9 (broad region; genes not listed).
- chr15:82,533,175–84,806,445, 80 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr15:85,255,369–85,330,334, 1 gene, copy number 9 (within-gene range 7–9): ADAMTS7P4.
- chr15:85,380,571–86,116,747, 20 genes, copy number 9: AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1, LINC01584.
- chr15:86,138,269–86,173,270, 3 genes, copy number 9: RNA5SP400, AC016180.2, AC016180.1.
- chr15:91,853,708–96,842,384, 94 genes, copy number 9 (broad region; genes not listed).
- chr19:5,558,167–13,778,773, 458 genes, copy number 9 (broad region; genes not listed).
- chr19:13,796,574–13,796,933, 1 gene, copy number 9: AC020916.2.
- chr20:33,702,758–34,347,785, 22 genes, copy number 16: PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1.
- chr20:34,384,165–34,384,265, 1 gene, copy number 16: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
